Somatic mutation profile of tumor specimen 0DNMAS from CCDI case PBCBRR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,646 days).
Specimen 0DNMAS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68251c47-51b9-43d0-8216-51821ff5fdd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNMA2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6513406-eb61-4b1c-9bc3-5a4c414e3db8

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 403/850 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5197G>T p.E1733* | Nonsense Mutation (SNP) | VAF 411/869 reads (47%) | catalogued as COSV61373497; called by muse, mutect2, varscan2
- COL11A1 | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 301/698 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.971); catalogued as rs770191756, COSV62177542; called by muse, mutect2, varscan2
- DDX3X | c.1036G>C p.D346H (on ENST00000399959; = p.D347H on NM_001356.5) | Missense Mutation (SNP) | VAF 308/761 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863429; called by muse, mutect2, varscan2
- GLRA4 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 279/687 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65456508; called by muse, mutect2, varscan2
- KDM4B | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 203/423 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs1487362954, COSV50211557; called by muse, mutect2, varscan2
- NTRK3 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 557/1239 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.895); catalogued as rs751831141, COSV100447458; called by muse, mutect2, varscan2
- PLCH1 | c.3726T>A p.F1242L (on ENST00000340059 / NM_001130960.2; = p.F1234L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 301/695 reads (43%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV58202103; called by muse, mutect2, varscan2
- PTPRF | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 238/500 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs367652888; called by muse, mutect2, varscan2
- SMARCA4 | c.3574C>G p.R1192G | Missense Mutation (SNP) | VAF 380/837 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60787617, COSV60789344; called by muse, mutect2, varscan2
- CACNA1D | c.2630T>C p.V877A (on ENST00000350061 / NM_001128840.3; = p.V897A on NM_000720.4) | Missense Mutation (SNP) | VAF 340/790 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2
- KMT2D | c.4718del p.V1573Gfs*3 | Frame Shift Del (DEL) | VAF 230/556 reads (41%) | called by mutect2, varscan2
- KRT85 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 316/621 reads (51%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 339/814 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ZNF335 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 310/675 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTF2A2 | c.285T>C p.I95= | Silent (SNP) | VAF 354/742 reads (48%) | called by muse, mutect2, varscan2
- KREMEN2 | c.1044C>T p.D348= | Silent (SNP) | VAF 84/614 reads (14%) | called by muse, mutect2, varscan2
- PRR5L | c.822G>A p.E274= | Silent (SNP) | VAF 310/651 reads (48%) | called by muse, mutect2, varscan2
- TEKT1 | c.387C>T p.H129= | Silent (SNP) | VAF 182/431 reads (42%) | catalogued as rs149847520; called by muse, mutect2, varscan2
- ZC3H7A | c.918C>A p.V306= | Silent (SNP) | VAF 178/371 reads (48%) | called by muse, mutect2, varscan2
